Gene-level copy-number profile of tumor specimen HTMCP-01-02-00013-01A from CGCI case HTMCP-01-02-00013, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 54.2 years (19,786 days).
Specimen HTMCP-01-02-00013-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 82b2591e-e99d-4069-9ee2-18116c1e2fae.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-02-00013-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/1cdee119-a733-4384-b50e-e6be73322bd7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 590; copy number 1: 4,112; copy number 2: 47,256; copy number 3: 5,975; copy number 4: 705; copy number 5: 90; copy number 6: 48; copy number 7: 31; copy number 16: 33; copy number 18: 29; copy number 23: 14; copy number 25: 19.

Homozygous deletions (total copy number 0; autosomes only): 78 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,245,596, 34 genes (within-gene range 0–3): IGKC, IGKJ5, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr14:106,421,711–106,422,218, 1 gene (within-gene range 0–1): IGHV4-39.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–1): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–1): IGHV3-43.
- chr22:22,689,831–22,896,111, 38 genes: AC244250.2, AC244250.1, IGLV3-24, IGLV2-23, IGLVVI-22-1, IGLV3-22, IGLV3-21, IGLVI-20, IGLV3-19, AC244250.3, IGLV2-18, IGLV3-17, IGLV3-16, IGLV3-15, IGLV2-14, IGLV3-13, IGLV3-12, AC244157.1, AC244157.2, IGLV2-11, AC245028.3, IGLV3-10, AC245028.1, IGLV3-9, IGLV2-8, MIR650, AC245028.2, IGLV3-7, IGLV3-6, IGLV2-5, IGLV3-4, IGLV4-3, IGLV3-2, IGLV3-1, MIR5571, IGLL5, IGLJ1, IGLC1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 264 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:125,528,858–126,301,213, 31 genes, copy number 7: OSBPL11, AF186996.3, AF186996.2, OR7E130P, OR7E29P, OR7E93P, OR7E53P, OR7E97P, AF186996.1, AC092902.4, AC092902.2, AC092902.1, MIR548I1, RPS3AP14, SNRPCP11, LINC02614, ENPP7P4, AC092903.2, FAM86JP, ALG1L, AC092903.1, ROPN1B, SLC41A3, AC117422.1, AC079848.1, ALDH1L1, ALDH1L1-AS1, RNU1-30P, ALDH1L1-AS2, AC016924.1, AC063919.1.
- chr9:3,824,127–7,175,648, 80 genes, copy number 6–25 (broad region; genes not listed).
- chr9:10,613,202–14,472,407, 34 genes, copy number 5–6: PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1.
- chr9:35,962,195–38,069,227, 55 genes, copy number 16–23 (within-gene range 4–23): OR2S1P, YBX1P10, OR13C6P, OR13C7, OR2AM1P, RECK, AL138834.1, GLIPR2, CCIN, CLTA, GNE, RNU4-53P, HMGB3P24, RNF38, MELK, AL450267.2, MIR4475, PAX5, AL450267.1, MIR4540, MIR4476, AL161781.2, AL161781.1, LINC01400, AL512604.3, EBLN3P, AL512604.2, ZCCHC7, Y_RNA, AL512604.1, Y_RNA, RNU6-677P, LINC01627, GRHPR, CHCHD4P3, ZBTB5, KCTD9P3, POLR1E, AL158156.1, AL513165.1, FBXO10, AL513165.2, TOMM5, AL138752.2, RAB1C, FRMPD1, RN7SKP171, TRMT10B, EXOSC3, DCAF10, AL138752.1, PAICSP1, SLC25A51, TMX2P1, SHB.
- chr9:41,233,755–60,547,154, 56 genes, copy number 5: MIR4477A, RNA5SP530, AL845472.1, PTGER4P2-CDK2AP2P2, CDK2AP2P1, MYO5BP1, AL354718.2, CDRT15P6, AL354718.1, AL591926.3, SNORA70, RN7SL565P, AL591926.7, AL591926.6, AL591926.5, AL591926.2, FAM242F, Y_RNA, AL591926.1, AL591926.4, AL162731.1, CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5, BX088651.3, FGF7P4, BX664718.1, BX664718.2, ADGRF5P2, MEP1AP4, ANKRD20A7P, RNU6-599P, CR848007.2, SNX18P5, CYP4F60P, CR848007.1, CNN2P4, AL591441.1, FP325317.1, FP325317.2, BX088702.1.
- chr11:95,482,406–95,497,553, 1 gene, copy number 5: AP001790.1.
- chr11:109,002,465–109,583,907, 7 genes, copy number 5: AP003123.1, RNU6-654P, RNA5SP349, SNORD39, AP003049.2, C11orf87, AP003049.1.

Autosomal genes at a single copy (total copy number 1): 4,112. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
